Surgical pathology report (de-identified scan), TCGA case TCGA-XV-AB01, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-AB01-06A (Metastatic).

Pathology Report

Date:

Patient ID:

Age:

Sex:

F

Clinical Dx:

Melanoma

Tumor Location:

Skin

Localization:

Subclavicular L/N

Source:

Epithelial melanoma

Clark Level (1-5):

n/a

Breslow (mm):

n/a

Tumor:

3

Normal:

0

Metastasis:

0

Stage (I-IV):

III

Tumor size (mm x mm):

4x5

NeoAdj ImmunoTx:

No

ICD O-3

Melanoma NOS 8720/3
Site: Subclavicular lymph node
C77.3

W 3/12/14

Source: NCI Genomic Data Commons file 9204aa43-17be-4332-bf39-f365611712ad (TCGA-XV-AB01.B8CB9A37-AE59-47F1-A727-B33B7179381F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).